TCGA case TCGA-D8-A1XW — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/887b9e5b-99db-44ac-9c30-c0dc6877b41c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 53 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,478 days); Year of diagnosis: 2011; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Left Upper Inner.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 181 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 118 days; Disease response: Tumor Free.
- Days to follow up: 385 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 1,309 days (3.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative; Staining intensity value: 1+.
- ESR1 (IHC): Negative.
- PGR (IHC): Positive; Test value range: <10%.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D8-A1XW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 310 mg.
  Slide TCGA-D8-A1XW-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-D8-A1XW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D8-A1XW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Er positivity method: % IHC; Axillary staging method: Sentinel lymph node biopsy plus axillary dissection; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Her2 IHC score: 1+; Method initial path diagnosis: Fine needle aspiration biopsy; Er positivity scale other: 0%; Prospective collection: Yes; Retrospective collection: No; Pr status IHC percent positive: <10%; Metastatic tumor indicator: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Left Upper Inner Quadrant.
- Follow-up form 1: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment: Pharmaceutical therapy drug name: adriamycin+cyclophosphamide.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,309 days; disease-specific survival: no event (censored), 1,309 days; disease-free interval: no event (censored), 1,309 days; progression-free interval: no event (censored), 1,309 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D8-A1XW-01A-11D-A14J-01): tumor purity 0.64, ploidy 2.5, whole-genome doublings 1.
